Surgical pathology report (de-identified scan), TCGA case TCGA-GL-A4EM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GL-A4EM-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

carcinoma, papillary renal cell 8260/3
Site: Kidney C64.9

lu
9/25/12

Operative Procedure:
Right partial nephrectomy

Specimen Received:
Right renal mass

Final Pathologic Diagnosis:
Kidney, right, partial nephrectomy:
Tumor histologic type: Papillary renal cell carcinoma, type 2

Sarcomatoid features (%): No
Tumor size: greatest dimension 4.8 cm
Other dimensions: 4.2 x 3.8 cm
Macroscopic extent of tumor: Tumor is confined to the kidney
Focality: Unifocal
If multifocal, number of tumors: Not applicable
Fuhrman grade: 3 of 4
Perinephric fat invasion: No
Renal sinus invasion: Not examined
Renal vein involvement: Not examined
Adrenal gland present: No
If yes, involved by tumor: Not applicable
If yes, direct invasion or metastasis: Not applicable
Cancer at resection margin: No, See Note
If yes, location(s): Not applicable
Pathologic findings in nonneoplastic kidney: None
Hilar lymph nodes present: No
If yes, number involved/number present: Not applicable

Pathologic stage (2010): pT1b__ pNX_ pM-Not applicable

The examination of this case material and the preparation of this report were
performed by the staff pathologist.

Gross Description:

The specimen is received in formalin labeled with the patient name and "right renal mass" and consists of
a 4.8 x 4.2 x 3.8 cm partial
nephrectomy specimen. The specimen appears to be entirely made up by the mass.
The mass has a soft heterogeneous multiloculated yellow-tan and hemorrhagic cut
surface. A portion of this mass has been previously collected by the Tissue Bank. A gross photograph
has also been taken of the specimen.
There does not appear to be any attached uninvolved renal parenchyma.
Representative sections are submitted in cassettes 1-5.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination

[page 2 of 2]
findings.

END OF REPORT

Taken:

Gender: M

Source: NCI Genomic Data Commons file 1a209749-f68d-4acd-9a54-9f7106e26abc (TCGA-GL-A4EM.6A217FA6-520D-4E6E-95B1-FBA67A4605C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).